TCGA case TCGA-02-0011 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33ae5566-3c72-4cae-b516-1708db090e32

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 18 years; Vital status: Dead; Days to death: 630 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 19.0 years (6,926 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 61 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 20 days; Days to treatment end: 145 days; Number of cycles: 4; Treatment dose: 75 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 145 days; Number of cycles: 4; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gefitinib; Initial disease status: Recurrent Disease.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 19.4 years (7,071 days); Days to diagnosis: 145 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 145 (post initial treatment): Progression or recurrence: Yes; Days to progression: 145 days.
- Days to follow up: 630 days (1.7 years); Disease response: With Tumor.
- Karnofsky performance status: 80.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0011-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.1.
  Slide TCGA-02-0011-01B-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-02-0011-01B-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-02-0011-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-02-0011-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Therapy regimen: Recurrence.
- Drug treatment 4: Pharmaceutical therapy drug name: Iressa; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 630 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 630 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 145 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0011-01): tumor purity 0.89, ploidy 1.88, whole-genome doublings 0 (call status: legacy_call).
